Somatic mutation profile of tumor specimen TCGA-AP-A1E1-01A (aliquot TCGA-AP-A1E1-01A-11D-A135-09) from TCGA case TCGA-AP-A1E1, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 74.1 years (27,072 days).
Specimen TCGA-AP-A1E1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f214a854-64bb-4b1e-8812-beb04f98ffa3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A1E1-10A (Blood Derived Normal), aliquot TCGA-AP-A1E1-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2745c33e-ae83-4954-9ff1-88bdb4fd1e9e

The open-access MAF lists 635 somatic variants for this specimen: 497 protein-altering or splice-affecting, 124 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 335, Silent 124, Frame Shift Del 107, Frame Shift Ins 22, Nonsense Mutation 19, RNA 6, Splice Site 5, In Frame Del 4, Splice Region 4, Intron 3, 5'UTR 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 8/17 reads (47%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 21/52 reads (40%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CTNNB1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 24/86 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778104039, COSV57252908; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 22/44 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- PIK3CA | c.3062A>G p.Y1021C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913288, CM126695, COSV55882161, COSV55997924; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- SGSH | c.356-2A>G p.X119_splice | Splice Site (SNP) | VAF 9/24 reads (38%) | catalogued as rs1057517927, COSV100413541; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADAC | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV99233421; called by muse, mutect2, varscan2
- ABCA12 | c.6108T>G p.I2036M (on ENST00000272895 / NM_173076.3; = p.I1718M on NM_015657.3) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99791193; called by muse, mutect2, varscan2
- ABCB8 | c.1757G>A p.R586Q (on ENST00000297504 / NM_001282291.2; = p.R569Q on NM_007188.5) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.148); catalogued as rs374442680; called by muse, mutect2, varscan2
- ABCC10 | c.1750G>T p.A584S (on ENST00000372530 / NM_001198934.2; = p.A541S on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99767691; called by muse, mutect2, varscan2
- ABCC12 | c.3866C>A p.S1289Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV100253011; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1045G>A p.V349M | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs553270370, COSV101352268; called by muse, mutect2, varscan2
- ACSBG2 | c.671G>A p.C224Y | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs376063152; called by muse, mutect2, varscan2
- ACSL4 | c.1240G>A p.G414R (on ENST00000340800 / NM_022977.2; = p.G373R on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs750557962, COSV100538853; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM20 | c.226A>G p.M76V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV99833527; called by muse, mutect2, varscan2
- ADAMTS14 | c.1412T>C p.L471P | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100941756; called by muse, mutect2, varscan2
- ADAMTS18 | c.1604G>A p.G535D | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99273666; called by muse, mutect2, varscan2
- ADGRE2 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.757); catalogued as rs202025706, COSV59695375; called by muse, mutect2
- AEBP1 | c.2951G>A p.R984H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1354983673, COSV56256699; called by muse, mutect2, varscan2
- AFF3 | c.1561_1563del p.K521del | In Frame Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs762540363; called by mutect2, pindel, varscan2
- AGTR2 | c.639A>C p.L213F | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.35); PolyPhen benign (0.327); catalogued as COSV100903602; called by muse, mutect2, varscan2
- AHNAK | c.1576C>A p.Q526K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV99948736; called by muse, mutect2, varscan2
- AIM2 | c.60G>T p.E20D | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.053); catalogued as COSV100931123; called by muse, mutect2
- ANGEL2 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100853975; called by muse, mutect2, varscan2
- ANK1 | c.2939C>A p.P980H | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99226198; called by muse, mutect2, varscan2
- ANKFY1 | c.3065C>T p.A1022V (on ENST00000341657 / NM_001330063.2; = p.A1023V on NM_016376.5) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs770970574, COSV100492981; called by muse, mutect2, varscan2
- ANKMY1 | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV99802853; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs1296524808; called by mutect2, varscan2
- ANXA11 | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs199988035; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs749401724; called by mutect2, varscan2
- ARHGEF16 | c.1921_1923del p.F641del | In Frame Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs756467358; called by pindel, varscan2
- ARID1A | c.4698G>C p.R1566S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as COSV100252679; called by muse, mutect2, varscan2
- ARL13A | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as rs373334251, COSV100879029, COSV100879043; called by muse, mutect2, varscan2
- ASPM | c.3501A>T p.Q1167H | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99660851; called by muse, mutect2, varscan2
- ASPM | c.305A>T p.E102V | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99660854; called by muse, mutect2, varscan2
- ATG2A | c.4756C>T p.R1586W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772991379, COSV101034647; called by muse, mutect2, varscan2
- ATP10A | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1186917803, COSV63522908; called by muse, mutect2, varscan2
- ATP8B2 | c.2750T>C p.M917T (on ENST00000672630; = p.M884T on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV100528152; called by muse, mutect2, varscan2
- ATRX | c.3310A>G p.R1104G | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV64874477; called by muse, mutect2
- AXIN1 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV99250138; called by muse, mutect2
- B4GALNT4 | c.918del p.R307Vfs*100 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | catalogued as rs770737105, COSV57327371; called by mutect2, pindel
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as rs35951843; called by mutect2, pindel, varscan2
- BACE2 | c.305del p.P102Rfs*25 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as rs771098505; called by mutect2, pindel, varscan2
- BAHCC1 | c.5588A>G p.E1863G | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100311922; called by muse, mutect2, varscan2
- BCAN | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100228325; called by muse, mutect2, varscan2
- BCL9 | c.3292G>A p.V1098M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781904363, COSV52340747; called by muse, mutect2, varscan2
- BLM | c.2803A>G p.I935V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.205); catalogued as rs774916971, COSV100757284; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMPR1B | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99216122; called by mutect2, varscan2
- BNIP5 | c.1702dup p.Y568Lfs*24 | Frame Shift Ins (INS) | VAF 6/23 reads (26%) | catalogued as rs747868798; called by mutect2, varscan2
- BRD1 | c.1423C>T p.R475* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as COSV99350056; called by muse, mutect2, varscan2
- BRF1 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); catalogued as rs147106237; called by mutect2, varscan2
- C1QTNF3 | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.884); catalogued as COSV99180723; called by muse, mutect2
- C2CD5 | c.1401A>G p.I467M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as COSV100448927; called by muse, mutect2, varscan2
- CACNA1D | c.3736G>A p.G1246R (on ENST00000350061 / NM_001128840.3; = p.G1266R on NM_000720.4) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV99859339; called by muse, mutect2, varscan2
- CACNA1S | c.5210C>A p.P1737H | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.219); catalogued as COSV100755213, COSV62941889; called by muse, mutect2, varscan2
- CACNA2D2 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs781210506, COSV99818083; called by muse, mutect2, varscan2
- CACYBP | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.054); catalogued as COSV100871549; called by muse, mutect2, varscan2
- CARMIL2 | c.4147G>A p.V1383I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs755266316, COSV99537915; called by muse, mutect2, varscan2
- CAVIN2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100414294; called by muse, mutect2, varscan2
- CBLN1 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1188699698, COSV99535649; called by muse, mutect2, varscan2
- CBX1 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.05); catalogued as COSV99848218; called by muse, mutect2
- CC2D2A | c.3280del p.L1094Sfs*5 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | catalogued as rs1332793509; called by mutect2, pindel, varscan2
- CCDC146 | c.2775A>C p.K925N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99592960; called by muse, mutect2, varscan2
- CCDC158 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.96); catalogued as COSV101187324; called by muse, mutect2, varscan2
- CCDC174 | c.1259A>T p.D420V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV99514342; called by muse, mutect2, varscan2
- CCND1 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57119102, COSV57119569, COSV57120578; called by muse, mutect2, varscan2
- CCT6A | c.1410T>A p.H470Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.056); catalogued as COSV99303643; called by muse, mutect2, varscan2
- CD177 | c.1258del p.V420Wfs*30 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as COSV65121341; called by mutect2, pindel, varscan2
- CD34 | c.259A>G p.T87A | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100178436; called by muse, mutect2, varscan2
- CDC73 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100813935; called by muse, mutect2, varscan2
- CDHR5 | c.1827del p.G610Vfs*159 (on ENST00000358353 / NM_001171968.2; = p.G616Vfs*159 on NM_021924.5) | Frame Shift Del (DEL) | VAF 18/150 reads (12%) | catalogued as COSV57643260; called by mutect2, varscan2
- CDK18 | c.1048A>G p.T350A (on ENST00000506784 / NM_212503.3; = p.T320A on NM_002596.4) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV100774078; called by muse, mutect2, varscan2
- CDKN2C | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.194); catalogued as rs1372032935, COSV52954547; called by muse, mutect2, varscan2
- CEACAM5 | c.1547A>C p.K516T | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.503); catalogued as COSV99704075; called by muse, mutect2, varscan2
- CEP170B | c.607G>A p.D203N (on ENST00000453495; = p.D132N on NM_015005.3) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.022); catalogued as COSV101371566; called by muse, mutect2, varscan2
- CERS4 | c.524T>C p.L175P | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99250730; called by muse, mutect2, varscan2
- CERS5 | c.1111A>G p.S371G | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100452043, COSV100452098; called by muse, mutect2, varscan2
- CFAP251 | c.2744C>T p.S915L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as rs754845886, COSV56607989; called by muse, mutect2, varscan2
- CHRD | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.025); catalogued as COSV52606946, COSV99200595; called by muse, mutect2
- CHRDL1 | c.211C>T p.R71* (on ENST00000372045; = p.R77* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as rs775515705, CM148186, COSV54323255; called by muse, mutect2, varscan2
- CLASP2 | c.3134G>T p.R1045L (on ENST00000359576; = p.R1044L on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV56291290; called by muse, mutect2, varscan2
- CLCA4 | c.629G>T p.C210F | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs2231587, COSV99760698; called by muse, mutect2, varscan2
- CLTCL1 | c.3661G>A p.V1221I | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV99595544; called by muse, mutect2
- CLUAP1 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100489750; called by muse, mutect2, varscan2
- CNGA2 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.083); catalogued as rs139547840, COSV100323857; called by muse, mutect2, varscan2
- CNNM3 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.872); catalogued as rs140550487; called by muse, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs374805044; called by mutect2, varscan2
- COIL | c.485del p.N162Tfs*47 | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | catalogued as rs769265872; called by mutect2, varscan2
- COL4A2 | c.4275dup p.G1426Rfs*30 | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | catalogued as rs34603892; called by mutect2, varscan2
- COL5A1 | c.2037G>A p.G679= | Splice Region (SNP) | VAF 5/65 reads (8%) | catalogued as COSV100880289; called by muse, mutect2
- COL9A3 | c.1804G>A p.G602R | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100102348; called by muse, mutect2, varscan2
- COLEC12 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as rs1257878281, COSV101232121; called by muse, mutect2, varscan2
- COLGALT1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1459747920, COSV99394846, COSV99395194; called by muse, mutect2, varscan2
- COPS6 | c.331C>A p.Q111K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.863); catalogued as COSV100385076; called by muse, mutect2
- CTAG2 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.89); catalogued as rs782686361, COSV55994621; called by muse, mutect2, varscan2
- CTDP1 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs143317014; called by muse, mutect2, varscan2
- CUL4A | c.542A>G p.H181R (on ENST00000375440 / NM_001008895.4; = p.H81R on NM_003589.3) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV100417442; called by mutect2, varscan2
- CYP24A1 | c.872A>C p.E291A | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as COSV99398484; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | catalogued as COSV99245498; called by mutect2, varscan2
- DCAF15 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.026); catalogued as rs766981125, COSV54329817; called by muse, mutect2, varscan2
- DCSTAMP | c.877C>A p.L293M | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.285); catalogued as COSV52578819; called by muse, mutect2
- DCUN1D2 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs775772172, COSV100215290; called by muse, mutect2, varscan2
- DDB1 | c.3173T>C p.L1058P | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100074759; called by muse, mutect2, varscan2
- DDX51 | c.1736A>G p.N579S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.951); catalogued as rs1235059542, COSV100223143; called by muse, mutect2, varscan2
- DHX32 | c.575T>A p.I192N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV99501838; called by muse, mutect2, varscan2
- DIRAS2 | c.536A>G p.D179G | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV101005886; called by muse, mutect2, varscan2
- DISP1 | c.1766C>A p.P589H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV99451736; called by muse, mutect2, varscan2
- DISP2 | c.3223G>A p.V1075M | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as rs774758324, COSV99140309; called by muse, mutect2, varscan2
- DIXDC1 | c.1649G>A p.R550H (on ENST00000440460 / NM_001037954.4; = p.R339H on NM_033425.4) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201418275; called by muse, mutect2, varscan2
- DMXL1 | c.4855C>T p.R1619C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201096718, COSV100224530; called by muse, mutect2, varscan2
- DNAH11 | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as rs200824684; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH2 | c.5318C>A p.S1773* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as COSV101209507, COSV66723267; called by muse, mutect2, varscan2
- DNAH5 | c.7553T>C p.L2518P | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV99452306; called by muse, mutect2
- DNAH8 | c.1646C>G p.A549G | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as COSV100546596, COSV59425723; called by muse, mutect2
- DNHD1 | c.13104A>G p.P4368= | Splice Region (SNP) | VAF 8/34 reads (24%) | catalogued as rs773740822, COSV99600655; called by muse, mutect2, varscan2
- DSP | c.659G>T p.S220I | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV101131576; called by muse, mutect2
- DTWD1 | c.395A>G p.E132G | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1442108862, COSV99233736; called by muse, mutect2
- DYNC1I1 | c.1387A>T p.T463S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100268873; called by muse, mutect2, varscan2
- EFHC1 | c.1457G>A p.G486D | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs1407316128, COSV100932105; called by muse, mutect2, varscan2
- EFNB1 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV99214940; called by muse, mutect2, varscan2
- ELF2 | c.1326G>A p.M442I (on ENST00000379550 / NM_001331036.2; = p.M382I on NM_006874.4) | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99643142; called by muse, mutect2
- ELMO1 | c.78+2T>C p.X26_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100165425; called by muse, mutect2, varscan2
- ELMOD3 | c.782C>A p.A261D | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV99809524; called by muse, mutect2, varscan2
- ENPP4 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100320405; called by muse, mutect2, varscan2
- EPRS1 | c.3039-2A>G p.X1013_splice | Splice Site (SNP) | VAF 7/71 reads (10%) | catalogued as rs749937045, COSV100859441; called by muse, mutect2, varscan2
- ESPN | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.013); catalogued as rs1456381382, COSV100911494; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 32/49 reads (65%) | catalogued as rs775950025; called by mutect2, varscan2
- EXOC3L2 | c.2240del p.P747Lfs*49 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs1261630384; called by mutect2, pindel, varscan2
- F2 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100319627; called by muse, mutect2, varscan2
- FAM110B | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as rs982486133, COSV64065391; called by muse, mutect2, varscan2
- FAM71E1 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1361630129, COSV100618524; called by muse, mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs746983128; called by mutect2, varscan2
- FARP2 | c.2134G>A p.A712T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as rs143386517, COSV50877430; called by muse, mutect2, varscan2
- FBH1 | c.980G>A p.C327Y (on ENST00000362091 / NM_178150.3; = p.C378Y on NM_032807.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1400693289, COSV62984649; called by muse, mutect2, varscan2
- FBLN2 | c.3112G>A p.E1038K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.55); catalogued as rs753003441, COSV99852365; called by muse, mutect2, varscan2
- FBXW10 | c.3127G>A p.A1043T | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV57059076; called by muse, mutect2, varscan2
- FCAR | c.296A>G p.Q99R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs911806391, COSV100629143; called by muse, mutect2, varscan2
- FGD1 | c.2648G>A p.R883Q | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.19); catalogued as rs1231705653, COSV100911216; called by muse, mutect2, varscan2
- FLG | c.4018G>T p.G1340* | Nonsense Mutation (SNP) | VAF 16/303 reads (5%) | catalogued as COSV100911901; called by muse, mutect2
- FLNB | c.3321C>A p.Y1107* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV55893596; called by muse, mutect2, varscan2
- FMR1 | c.1471+2T>G p.X491_splice | Splice Site (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99503584; called by muse, mutect2, varscan2
- FREM1 | c.6362C>T p.A2121V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV101085102, COSV66527421; called by muse, mutect2, varscan2
- FUBP1 | c.483dup p.R162Tfs*8 | Frame Shift Ins (INS) | VAF 15/48 reads (31%) | catalogued as rs1405120226; called by mutect2, pindel, varscan2
- FURIN | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as rs1274395518, COSV99184749; called by muse, mutect2, varscan2
- FUT4 | c.1588C>T p.R530W | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs151024645, COSV100708147; called by muse, mutect2, varscan2
- G3BP1 | c.1203G>A p.M401I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as COSV100664020; called by muse, mutect2
- GAPDH | c.420T>A p.Y140* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as COSV99975620; called by muse, mutect2
- GAPDHS | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs967166360, COSV55884150, COSV99722854; called by muse, mutect2, varscan2
- GAPVD1 | c.908G>T p.R303M | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99783541; called by muse, mutect2, varscan2
- GEN1 | c.130del p.M44* | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | catalogued as rs748084139; called by mutect2, pindel, varscan2
- GHRL | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.272); catalogued as rs1314216218, COSV99813665; called by muse, mutect2, varscan2
- GJA5 | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99605738; called by muse, mutect2, varscan2
- GLP1R | c.440T>C p.I147T | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV100952685; called by muse, mutect2
- GLRA4 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs746558748, COSV101009505, COSV65455041; called by muse, mutect2, varscan2
- GOLGA3 | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs758836540, COSV99202308; called by muse, mutect2, varscan2
- GPR101 | c.1478G>T p.G493V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99981554; called by muse, mutect2, varscan2
- GPRC5A | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs200518388, COSV50007478; called by muse, mutect2, varscan2
- GRID1 | c.2039G>A p.G680D | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100026956, COSV60013590; called by muse, mutect2
- GRK6 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV100586980; called by muse, mutect2, varscan2
- GRM1 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs773266243, COSV51367039; called by muse, varscan2
- GRM7 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1290535694, COSV100737675; called by muse, mutect2, varscan2
- GSPT1 | c.502A>T p.N168Y (on ENST00000420576 / NM_001130007.2; = p.N306Y on NM_002094.4) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs758365024, COSV101341756; called by muse, mutect2, varscan2
- GTF2H4 | c.407T>C p.L136P | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV99462056; called by muse, mutect2, varscan2
- GUSB | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV59220986, COSV59224924; called by muse, mutect2, varscan2
- H2AJ | c.29A>C p.K10T | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.555); catalogued as COSV100797665; called by muse, mutect2
- H4C9 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100574923; called by muse, mutect2, varscan2
- HECTD1 | c.5174A>G p.H1725R | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.025); catalogued as rs779400024, COSV101237450; called by muse, mutect2, varscan2
- HECW2 | c.271T>C p.W91R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53648994, COSV99648230; called by muse, mutect2, varscan2
- HNRNPU | c.1378G>T p.G460C (on ENST00000283179; = p.G522C on NM_004501.3) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99310544; called by muse, mutect2, varscan2
- HPSE | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.957); catalogued as COSV60985780; called by muse, mutect2, varscan2
- HS3ST4 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100502341, COSV58821272; called by muse, mutect2, varscan2
- HSPG2 | c.1978C>T p.R660C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749956865, COSV101020960; called by muse, mutect2, varscan2
- IARS1 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.611); catalogued as rs150135423; called by muse, mutect2, varscan2
- IDH2 | c.435del p.T146Lfs*15 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as rs747216375; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- INSRR | c.3802dup p.A1268Gfs*13 | Frame Shift Ins (INS) | VAF 26/163 reads (16%) | catalogued as rs1224959325; called by mutect2, pindel, varscan2
- IRS1 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1447178819, COSV100524793; called by muse, mutect2, varscan2
- ITGAX | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs775534364, COSV51644463; called by muse, mutect2, varscan2
- KANSL1L | c.2858G>T p.G953V | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.131); catalogued as COSV99910793; called by muse, mutect2, varscan2
- KCNE4 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs762566965, COSV56054261, COSV56054378; called by muse, mutect2, varscan2
- KCNF1 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs1241881536, COSV54464273; called by muse, mutect2, varscan2
- KIF1C | c.1780G>A p.V594I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.959); catalogued as rs745324466, COSV100297264; called by muse, mutect2, varscan2
- KMT2C | c.12415C>T p.R4139* | Nonsense Mutation (SNP) | VAF 5/52 reads (10%) | catalogued as COSV51439890; called by muse, mutect2
- KMT2D | c.6022_6024del p.K2008del | In Frame Del (DEL) | VAF 7/18 reads (39%) | catalogued as rs1278007411; called by mutect2, varscan2
- KMT2D | c.3859del p.E1287Rfs*43 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as COSV56457044; called by mutect2, varscan2
- KRT77 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100527201; called by muse, mutect2, varscan2
- KRTAP10-4 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as rs587701380, COSV100554810; called by muse, mutect2, varscan2
- KRTAP10-4 | c.1198C>A p.L400I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100554811; called by muse, mutect2, varscan2
- KRTAP19-4 | c.200C>A p.P67H | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV100478549; called by muse, mutect2, varscan2
- LAMC1 | c.4022G>A p.R1341Q | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.325); catalogued as rs372436112; called by muse, mutect2, varscan2
- LAMC2 | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV99917723; called by muse, mutect2
- LCE2A | c.95G>A p.C32Y | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV100909205, COSV64227107; called by muse, mutect2, varscan2
- LCE3A | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.555); catalogued as rs761525258, COSV59550792; called by muse, mutect2, varscan2
- LCT | c.3631T>C p.S1211P | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV99930074; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as COSV65473126, COSV65473260; called by mutect2, pindel, varscan2
- LIMK1 | c.623G>A p.C208Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.296); catalogued as COSV100283347; called by mutect2, varscan2
- LIN54 | c.1262A>T p.N421I | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as COSV100464865; called by muse, mutect2
- LIN7B | c.329G>A p.G110D | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99674556; called by muse, mutect2, varscan2
- LRIG1 | c.1747T>G p.F583V | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99834103; called by muse, mutect2, varscan2
- LRP3 | c.659G>A p.S220N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.696); catalogued as COSV99472417; called by muse, mutect2, varscan2
- LRP5 | c.2780G>A p.G927D | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV99592427; called by muse, mutect2, varscan2
- LRRC15 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs536324527, COSV61650684; called by muse, mutect2, varscan2
- LRRC37A3 | c.1024G>C p.A342P | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV100141335; called by mutect2, varscan2
- LRRIQ3 | c.1134del p.P379Lfs*26 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs751977298; called by mutect2, pindel, varscan2
- MAF | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV58153485; called by muse, mutect2, varscan2
- MAGEA3 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100939074; called by muse, mutect2, varscan2
- MAK | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs773588644, COSV100504561; called by muse, mutect2, varscan2
- MAP3K3 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV62281682; called by muse, mutect2, varscan2
- MBOAT7 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs765063268, COSV99824956; called by muse, mutect2, varscan2
- MCF2 | c.962T>A p.L321H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100644967; called by muse, mutect2, varscan2
- MED14 | c.3146C>T p.A1049V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.097); catalogued as COSV100247573; called by muse, mutect2
- MED15 | c.2019C>A p.S673R (on ENST00000263205 / NM_001003891.3; = p.S633R on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV99487965; called by muse, mutect2, varscan2
- MED16 | c.1826A>T p.N609I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99516055; called by muse, varscan2
- MEGF10 | c.3151A>G p.M1051V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV99175235; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- METAP2 | c.433A>G p.T145A | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs776632195, COSV99704915; called by muse, mutect2, varscan2
- MGAM | c.2713C>A p.L905I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as rs371591084, COSV72073978; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MKKS | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV100726305; called by muse, mutect2
- MLH3 | c.1755del p.E586Nfs*24 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs751465048; called by mutect2, varscan2
- MMEL1 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.936); catalogued as rs141838137, COSV99984206; called by muse, mutect2, varscan2
- MRPL37 | c.179T>C p.F60S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV99839099; called by muse, mutect2, varscan2
- MS4A12 | c.556A>G p.N186D | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV99189416; called by muse, mutect2, varscan2
- MUC16 | c.36862A>G p.R12288G | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV101200633; called by muse, mutect2, varscan2
- MUC17 | c.5239G>T p.G1747* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV100074416; called by muse, mutect2, varscan2
- MUC4 | c.12852del p.T4285Qfs*142 (on ENST00000463781 / NM_018406.7; = p.T49Qfs*142 on NM_004532.6) | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | catalogued as rs747797305; called by mutect2, pindel, varscan2
- MXRA5 | c.6395G>A p.R2132H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs927390208, COSV54228105; called by muse, mutect2, varscan2
- MYLK | c.2487G>T p.E829D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.622); catalogued as COSV100659376; called by muse, mutect2, varscan2
- MYOF | c.3947T>C p.M1316T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1386073793; called by muse, mutect2
- N4BP2L2 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs142162740; called by muse, mutect2, varscan2
- NBEAL1 | c.5987A>G p.E1996G | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1286230573, COSV101355581; called by muse, mutect2, varscan2
- NBN | c.578T>A p.I193N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.265); catalogued as COSV99619870; called by muse, mutect2, varscan2
- NCKAP1L | c.1187C>A p.P396H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.955); catalogued as COSV99515466; called by muse, mutect2
- NEDD4 | c.1097G>T p.C366F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100163962; called by muse, mutect2, varscan2
- NFASC | c.1133A>G p.Q378R (on ENST00000339876 / NM_001378329.1; = p.Q389R on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100365012; called by muse, mutect2
- NFATC2 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1169527184, COSV101044415; called by mutect2, varscan2
- NHLH1 | c.321dup p.D108Rfs*8 | Frame Shift Ins (INS) | VAF 20/122 reads (16%) | catalogued as rs760805876; called by mutect2, pindel, varscan2
- NLRP5 | c.2353C>T p.Q785* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as rs200446614, CM158625, COSV66767721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOA1 | c.1699C>T p.H567Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs747984727, COSV51738788; called by muse, varscan2
- NOD1 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.671); catalogued as rs367963834, COSV56112139; called by muse, mutect2, varscan2
- NOS2 | c.3271G>A p.V1091M | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs200807678, COSV58224491; called by muse, mutect2, varscan2
- NOTCH2 | c.3726G>T p.M1242I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99865769; called by muse, mutect2
- NPAS4 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100215132; called by muse, mutect2, varscan2
- NPEPPS | c.2237C>A p.P746H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100443881; called by muse, mutect2, varscan2
- NR1H3 | c.922C>A p.P308T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.904); catalogued as COSV101269796; called by muse, mutect2, varscan2
- NRCAM | c.1844C>T p.T615M (on ENST00000379028 / NM_001371124.1; = p.T609M on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs112465984, COSV100695183; called by muse, mutect2, varscan2
- NRP1 | c.1676C>T p.T559M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.717); catalogued as rs143124682, COSV55174906; called by muse, mutect2, varscan2
- NUP210L | c.5390A>G p.H1797R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99668647; called by muse, mutect2, varscan2
- ODF3L1 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV100150807; called by muse, mutect2, varscan2
- OLAH | c.294del p.F98Lfs*15 (on ENST00000378228 / NM_001039702.3; = p.F151Lfs*15 on NM_018324.3) | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | catalogued as rs1452760362; called by mutect2, pindel, varscan2
- OLIG2 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV100324324; called by muse, mutect2, varscan2
- OPN4 | c.1178T>C p.L393P | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV54115333; called by muse, mutect2, varscan2
- OR10T2 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs372699275, COSV57780839; called by muse, mutect2, varscan2
- OR2B3 | c.73A>G p.M25V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV101013830; called by muse, mutect2, varscan2
- OR2L2 | c.581A>G p.Y194C | Missense Mutation (SNP) | VAF 14/281 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV100824216; called by muse, mutect2
- OR8B3 | c.577T>C p.Y193H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.139); catalogued as COSV100660429; called by muse, varscan2
- OSBPL2 | c.543dup p.I182Hfs*12 (on ENST00000313733 / NM_144498.4; = p.I170Hfs*12 on NM_014835.4) | Frame Shift Ins (INS) | VAF 11/56 reads (20%) | catalogued as rs780916980; called by mutect2, varscan2
- OTOF | c.4703G>C p.G1568A (on ENST00000272371 / NM_194248.3; = p.G801A on NM_004802.4) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99718430; called by muse, mutect2, varscan2
- P2RX4 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV100078764; called by muse, mutect2, varscan2
- PAQR7 | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.723); catalogued as COSV100961711; called by muse, mutect2, varscan2
- PCDH17 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV100931440; called by muse, mutect2
- PCDHA6 | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.082); catalogued as rs782487048, COSV65342166; called by muse, mutect2, varscan2
- PCDHGA3 | c.525T>G p.N175K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV99543200; called by muse, mutect2, varscan2
- PCDHGB6 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1368587420, COSV99543201; called by muse, mutect2
- PCDHGB6 | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs1426515605, COSV53926316; called by muse, mutect2
- PEG10 | c.965C>T p.P322L (on ENST00000482108 / NM_001040152.2; = p.P355= on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); catalogued as COSV101509934; called by muse, mutect2
- PEG3 | c.2071C>T p.R691W | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs148855175; called by muse, mutect2, varscan2
- PHF20 | c.2269C>T p.H757Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV64978909; called by muse, mutect2, varscan2
- PHF3 | c.5575_5577del p.V1859del | In Frame Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs765342543; called by pindel, varscan2
- PHKA1 | c.2939T>C p.V980A | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100263675; called by muse, mutect2, varscan2
- PIAS4 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as rs1241436975, COSV99518994; called by muse, mutect2, varscan2
- PIGO | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs753918558, COSV53056465; called by mutect2, varscan2
- PIGQ | c.1235T>C p.L412P | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV99216342; called by muse, mutect2
- PITPNM3 | c.157A>G p.M53V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99338769; called by muse, mutect2, varscan2
- PKHD1L1 | c.6567del p.K2189Nfs*27 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | catalogued as rs769716668, COSV65737892; called by mutect2, pindel, varscan2
- PLAAT3 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 24/68 reads (35%) | catalogued as rs142158004, COSV100071854; called by muse, mutect2, varscan2
- PLEKHH2 | c.3715C>T p.Q1239* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs1208282441, COSV99174961; called by muse, varscan2
- PLPPR2 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99264481; called by muse, mutect2, varscan2
- PNCK | c.365G>A p.G122D (on ENST00000340888 / NM_001366975.1; = p.G205D on NM_001039582.3) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.028); catalogued as COSV100562416, COSV61743355; called by muse, mutect2, varscan2
- POLR2B | c.1412A>C p.N471T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100108251; called by muse, mutect2, varscan2
- POT1 | c.1756A>G p.I586V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.294); catalogued as rs1554415137, COSV100714111; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POU1F1 | c.551G>A p.C184Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753790272, COSV60156004; called by muse, mutect2, varscan2
- PPM1J | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.471); catalogued as rs1252144036, COSV100497363; called by muse, mutect2, varscan2
- PPP1R12B | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as rs368051793; called by muse, mutect2, varscan2
- PPP2R5D | c.1168G>A p.V390I | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.215); catalogued as rs760706379, COSV99776609; called by muse, mutect2, varscan2
- PPRC1 | c.2819del p.P940Hfs*6 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | catalogued as rs768056539; called by mutect2, varscan2
- PRAMEF17 | c.883T>G p.L295V | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV101068775; called by muse, mutect2, varscan2
- PRICKLE3 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.409); catalogued as rs186856741, COSV100889937; called by muse, mutect2, varscan2
- PRKACB | c.145del p.T49Pfs*13 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | catalogued as rs1291568884; called by mutect2, pindel, varscan2
- PRKCQ | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99576716; called by muse, mutect2, varscan2
- PRKCZ | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs56017162; called by muse, mutect2, varscan2
- PRPF6 | c.2477G>T p.R826M | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99412501; called by muse, mutect2
- PRRC2A | c.5270G>A p.G1757D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV99277405; called by muse, mutect2, varscan2
- PRUNE2 | c.1808del p.N603Ifs*11 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | catalogued as rs754369178; called by mutect2, pindel
- PTCHD3 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.971); catalogued as COSV101438942; called by muse, mutect2, varscan2
- PTEN | c.164+1G>A p.X55_splice | Splice Site (SNP) | VAF 23/45 reads (51%) | catalogued as CD043800, CS013829, CS132270, CS147226, COSV64291461, COSV64302445, COSV64308544; called by muse, mutect2, varscan2
- PXDN | c.551T>C p.M184T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV99414414; called by muse, mutect2, varscan2
- QSOX1 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.27); catalogued as rs1235654162, COSV62581527; called by muse, mutect2, varscan2
- QTRT1 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.249); catalogued as rs768481230, COSV99139085; called by muse, mutect2, varscan2
- R3HCC1L | c.662C>G p.P221R | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100107464, COSV100107603; called by muse, mutect2, varscan2
- RABEP1 | c.411G>C p.E137D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV99336891; called by muse, mutect2, varscan2
- RABEP2 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100707154; called by muse, mutect2, varscan2
- RFC5 | c.256A>G p.M86V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs771566900, COSV99969975; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 20/33 reads (61%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPP25L | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.297); catalogued as rs1317154705, COSV99426985; called by muse, mutect2
- RRAGD | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV100784625; called by muse, mutect2, varscan2
- RUSF1 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs775036191, COSV100393333; called by muse, mutect2, varscan2
- RYR1 | c.6929G>A p.C2310Y | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV100616500, COSV62096611; called by muse, mutect2, varscan2
- RYR1 | c.14605G>T p.D4869Y | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100616502; called by muse, mutect2, varscan2
- RYR2 | c.773G>T p.R258I | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100772059; called by muse, mutect2, varscan2
- RYR2 | c.4997C>T p.A1666V | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100772060; called by muse, mutect2, varscan2
- SAP30 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56634531; called by mutect2, varscan2
- SBF1 | c.3228del p.S1077Afs*28 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs771002611; called by pindel, varscan2
- SDR42E1 | c.1132A>G p.I378V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100200761; called by muse, mutect2, varscan2
- SEPTIN5 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100820444; called by muse, mutect2, varscan2
- SERPINA11 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142259084; called by muse, mutect2, varscan2
- SF3A3 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.055); catalogued as COSV100885669; called by muse, mutect2, varscan2
- SH3GL1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs762971820, COSV53656986, COSV53659204; called by muse, mutect2, varscan2
- SKA3 | c.712A>G p.M238V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs776038030, COSV53435730; called by muse, mutect2, varscan2
- SLC12A4 | c.2416del p.R806Vfs*41 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as COSV50455128; called by mutect2, pindel, varscan2
- SLC16A7 | c.890G>T p.R297M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99676748; called by muse, mutect2, varscan2
- SLC1A1 | c.1315G>T p.V439F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99261515; called by muse, mutect2, varscan2
- SLC22A11 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as rs1412431218, COSV57252400; called by muse, mutect2, varscan2
- SLC32A1 | c.1328C>T p.T443M | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs892354307, COSV54145562; called by muse, mutect2, varscan2
- SLC4A11 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.179); catalogued as COSV101196099; called by muse, mutect2, varscan2
- SLC9A1 | c.354T>C p.G118= | Splice Region (SNP) | VAF 17/42 reads (40%) | catalogued as COSV99849898; called by muse, mutect2, varscan2
- SLFN5 | c.1256T>C p.L419S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100249765; called by muse, mutect2, varscan2
- SLITRK4 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs1158231525, COSV62024935; called by muse, mutect2, varscan2
- SMAD6 | c.1163G>A p.G388D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99994262; called by muse, mutect2, varscan2
- SMARCD2 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773052349, COSV99856556; called by muse, mutect2, varscan2
- SMCHD1 | c.1380A>G p.I460M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs1380609385, COSV99862176; called by muse, mutect2, varscan2
- SMURF2 | c.1462C>T p.R488* | Nonsense Mutation (SNP) | VAF 26/54 reads (48%) | catalogued as rs1202846325, COSV99300927; called by muse, mutect2, varscan2
- SNCAIP | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV99749693, COSV99749793; called by mutect2, varscan2
- SNIP1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV99953226; called by muse, mutect2, varscan2
- SOS2 | c.2784del p.F928Lfs*5 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | catalogued as rs1347298671; called by mutect2, pindel, varscan2
- SPAG16 | c.1384A>T p.I462F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100534707; called by muse, mutect2, varscan2
- SPAG6 | c.233C>A p.A78D | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.273); catalogued as COSV57620360; called by muse, mutect2, varscan2
- SPARCL1 | c.1469G>A p.C490Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99215794; called by muse, mutect2, varscan2
- SPDL1 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.69); PolyPhen benign (0.164); catalogued as rs768116350, COSV99517659; called by muse, mutect2, varscan2
- SPIRE2 | c.1331A>G p.H444R | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as rs1411702247, COSV100988920; called by muse, mutect2
- SREBF2 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100761514; called by muse, mutect2, varscan2
- SREK1IP1 | c.271del p.R91Gfs*67 | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | catalogued as rs750306056; called by mutect2, varscan2
- ST18 | c.2363G>T p.S788I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99390547; called by muse, mutect2
- STRA6 | c.127T>A p.C43S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100121207; called by muse, mutect2
- STRADA | c.944C>T p.S315L (on ENST00000336174 / NM_001363786.1; = p.S278L on NM_153335.6) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs375825074; called by muse, mutect2
- STXBP1 | c.808G>A p.G270S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as rs146566779; called by mutect2, varscan2
- SUN1 | c.1220C>T p.A407V (on ENST00000405266 / NM_001367651.1; = p.A287V on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV100568763; called by muse, mutect2, varscan2
- SYNE1 | c.12182C>T p.P4061L (on ENST00000367255 / NM_182961.4; = p.P3990L on NM_033071.3) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as rs148036239; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SZT2 | c.3647T>A p.L1216* (on ENST00000634258 / NM_001365999.1; = p.L1159* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100987527; called by muse, mutect2, varscan2
- TBC1D8B | c.2491C>T p.P831S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99344835; called by muse, mutect2, varscan2
- TBX18 | c.1142G>A p.G381D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100858551; called by muse, mutect2, varscan2
- TBXT | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99752755; called by muse, mutect2, varscan2
- TCL1B | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.506); catalogued as COSV100525820; called by muse, mutect2, varscan2
- TENM1 | c.1256G>C p.R419P | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100950499, COSV100950755; called by muse, mutect2, varscan2
- TENM1 | c.472del p.E158Kfs*64 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | catalogued as COSV64435693; called by mutect2, pindel, varscan2
- TENM3 | c.4396G>A p.A1466T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs371087410, COSV69299200; called by muse, mutect2, varscan2
- TET3 | c.4389G>T p.E1463D | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.028); catalogued as COSV101328006; called by muse, mutect2, varscan2
- TFE3 | c.1219A>G p.K407E | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV100252729; called by muse, mutect2, varscan2
- THRSP | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as rs954060535, COSV99806536; called by muse, mutect2, varscan2
- TIAM1 | c.865C>A p.L289I | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99737600; called by muse, mutect2, varscan2
- TLN1 | c.4153A>G p.N1385D | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV100148050; called by muse, mutect2, varscan2
- TMEM132B | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV100170463; called by muse, mutect2, varscan2
- TMEM266 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs756884747, COSV101189643; called by muse, mutect2, varscan2
- TMEM51 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); catalogued as rs779269565, COSV101051562; called by muse, mutect2, varscan2
- TMEM94 | c.2682del p.S895Pfs*13 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs747222326; called by mutect2, pindel, varscan2
- TNRC18 | c.4782del p.R1595Gfs*18 | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | catalogued as COSV68163741; called by mutect2, pindel, varscan2
- TNRC18 | c.4627dup p.R1543Pfs*10 | Frame Shift Ins (INS) | VAF 18/54 reads (33%) | catalogued as rs754233336; called by mutect2, varscan2
- TP63 | c.1628A>T p.Y543F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99288016; called by muse, mutect2, varscan2
- TPM1 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.212); catalogued as COSV99147341; called by muse, mutect2, varscan2
- TPR | c.6215A>C p.Q2072P | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100824151; called by muse, mutect2, varscan2
- TREH | c.1622G>C p.G541A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99874668; called by mutect2, varscan2
- TRIB2 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99331261; called by muse, mutect2, varscan2
- TRIM22 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.114); catalogued as COSV101181433, COSV66090566; called by muse, mutect2, varscan2
- TRIOBP | c.7039C>T p.R2347C (on ENST00000644935 / NM_001039141.3; = p.R634C on NM_007032.5) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs369681704; called by muse, mutect2, varscan2
- TRO | c.3521G>A p.S1174N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as COSV99436992; called by muse, mutect2, varscan2
- TRPM8 | c.3049G>A p.V1017I | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs897159839, COSV61225258; called by muse, mutect2, varscan2
- TRPS1 | c.2369G>A p.R790H (on ENST00000220888 / NM_001330599.2; = p.R803H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.813); catalogued as COSV55225702; called by muse, mutect2, varscan2
- TRPV2 | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 17/71 reads (24%) | catalogued as COSV100641306; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL13P | c.489G>A p.M163I | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV100296670; called by muse, mutect2, varscan2
- TTN | c.53458G>T p.V17820L (on ENST00000591111; = p.V10396L on NM_003319.4) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | PolyPhen benign (0.041); catalogued as rs368431326, COSV60300842; called by muse, mutect2, varscan2
- UBAP2 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.987); catalogued as rs545692957, COSV100671747; called by muse, mutect2, varscan2
- UBR4 | c.11984G>A p.S3995N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.111); catalogued as COSV100921398; called by muse, mutect2, varscan2
- UNC5D | c.1222A>G p.S408G | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.97); catalogued as COSV99777542; called by muse, mutect2
- USP26 | c.1461del p.F487Lfs*40 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs761320003; called by mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as rs764735138; called by mutect2, varscan2
- UTP20 | c.2269A>T p.K757* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99882172; called by muse, mutect2
- VAX2 | c.719del p.P240Hfs*36 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs782186760; called by mutect2, varscan2
- VCAN | c.9563G>A p.R3188H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs917249805, COSV54109411, COSV54115967; called by muse, mutect2, varscan2
- VPS13B | c.10139C>T p.A3380V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs199931583, COSV104420642, COSV62132903; called by muse, mutect2, varscan2
- VWCE | c.2753C>A p.P918H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.401); catalogued as rs748290731, COSV100076037, COSV57111740; called by muse, mutect2, varscan2
- VWF | c.5369C>T p.P1790L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs551649729, COSV54624764; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR27 | c.935T>A p.L312Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.08); catalogued as COSV100359460; called by mutect2, varscan2
- WNT5A | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as COSV52836127, COSV52837194; called by muse, mutect2, varscan2
- WSB2 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as rs1380046425, COSV99969976; called by muse, mutect2
- XPNPEP2 | c.1359del p.Q454Sfs*30 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs762212384; called by mutect2, pindel, varscan2
- YLPM1 | c.4717C>T p.R1573* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99459553; called by muse, mutect2, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs751577786; called by mutect2, varscan2
- ZFPM1 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100128628; called by muse, mutect2, varscan2
- ZKSCAN3 | c.1448A>G p.N483S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as COSV99357062; called by muse, mutect2
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZMYND19 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs1235562329, COSV100057285; called by muse, mutect2, varscan2
- ZMYND8 | c.1904del p.K635Sfs*14 (on ENST00000311275 / NM_001363741.2; = p.K655Sfs*14 on NM_012408.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs776813452; called by mutect2, varscan2
- ZNF284 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV101399046; called by muse, mutect2, varscan2
- ZNF385A | c.361G>T p.G121* (on ENST00000338010 / NM_001130967.3; = p.G101* on NM_015481.3) | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100566957; called by muse, mutect2, varscan2
- ZNF43 | c.752del p.N251Ifs*28 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs753886536; called by mutect2, varscan2
- ZNF468 | c.696del p.K232Nfs*4 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | catalogued as COSV54697628; called by mutect2, pindel, varscan2
- ZNF536 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.022); catalogued as rs778216938, COSV62834377; called by muse, mutect2, varscan2
- ZNF569 | c.2021A>C p.K674T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV57595773; called by muse, mutect2, varscan2
- ZNF687 | c.2162G>A p.S721N | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.07); catalogued as COSV99649995; called by muse, mutect2
- ZNF746 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs368614322; called by muse, mutect2, varscan2
- ZNF776 | c.1126T>G p.F376V | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs761340735, COSV100414286; called by muse, mutect2, varscan2
- ZP1 | c.1850G>T p.G617V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV99612682; called by muse, mutect2, varscan2
- ZRANB3 | c.2554G>T p.G852C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99924273; called by muse, mutect2, varscan2
- ABCA12 | c.6604del p.S2202Pfs*5 (on ENST00000272895 / NM_173076.3; = p.S1884Pfs*5 on NM_015657.3) | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- AGBL2 | c.837dup p.A280Sfs*8 | Frame Shift Ins (INS) | VAF 20/61 reads (33%) | called by mutect2, pindel, varscan2
- AGO1 | c.49del p.L17Cfs*99 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- AGO2 | c.970del p.H324Tfs*33 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- AKAP13 | c.7511del p.K2504Rfs*50 (on ENST00000394518 / NM_007200.5; = p.K2508Rfs*50 on NM_006738.6) | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- AMER2 | c.1193dup p.H399Afs*12 | Frame Shift Ins (INS) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- AP3B1 | c.2769del p.K923Nfs*4 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- ARHGEF12 | c.4396dup p.A1466Gfs*24 | Frame Shift Ins (INS) | VAF 7/61 reads (11%) | called by mutect2, pindel, varscan2
- ARHGEF5 | c.2444del p.P815Lfs*31 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by mutect2, pindel, varscan2
- ATP13A2 | c.1933G>T p.G645W | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- ATP8B1 | c.2610del p.K871Sfs*10 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
- AVL9 | c.730del p.S244Vfs*48 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, pindel, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | called by pindel, varscan2
- BLOC1S5 | c.286_287del p.D96Hfs*17 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by pindel, varscan2
- BRSK2 | c.1737del p.P580Qfs*55 | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | called by mutect2, pindel, varscan2
- CDC14A | c.477del p.F159Lfs*31 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- CDC6 | c.205dup p.H69Pfs*24 | Frame Shift Ins (INS) | VAF 4/18 reads (22%) | called by mutect2, pindel, varscan2
- CHD6 | c.216del p.P73Lfs*4 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- CPM | c.1263C>A p.D421E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- DOK7 | c.568del p.E190Sfs*56 | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | called by mutect2, pindel, varscan2
- ECT2 | c.2171del p.P724Qfs*9 (on ENST00000392692 / NM_001349098.2; = p.P693Qfs*9 on NM_018098.6 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | called by mutect2, pindel, varscan2
- EPN1 | c.1367del p.P456Hfs*33 (on ENST00000270460 / NM_001321263.1; = p.P430Hfs*33 on NM_013333.3) | Frame Shift Del (DEL) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- ETNPPL | c.986dup p.N329Kfs*2 | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | called by mutect2, varscan2
- ETV1 | c.1022del p.L341Wfs*2 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- F5 | c.311del p.N104Ifs*7 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | called by mutect2, pindel, varscan2
- FAM133A | c.157del p.T53Qfs*6 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- FANCI | c.3578del p.N1193Ifs*6 (on ENST00000310775 / NM_001376911.1; = p.N1133Ifs*6 on NM_018193.3) | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- FCRL3 | c.1290dup p.S431Lfs*22 | Frame Shift Ins (INS) | VAF 15/72 reads (21%) | called by mutect2, pindel, varscan2
- HEXB | c.1010del p.F337Sfs*35 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel
- HLA-B | c.626del p.P209Qfs*5 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | called by mutect2, varscan2
- HOXB3 | c.776del p.P259Hfs*18 | Frame Shift Del (DEL) | VAF 9/99 reads (9%) | called by mutect2, pindel, varscan2
- HTR7 | c.461del p.F154Sfs*18 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel, varscan2
- IGSF9B | c.439del p.Q147Sfs*13 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- ITPRIPL1 | c.493C>A p.Q165K (on ENST00000439118 / NM_001008949.3; = p.Q173K on NM_178495.6) | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- KMT2B | c.7946_7947dup p.F2650Afs*89 | Frame Shift Ins (INS) | VAF 11/27 reads (41%) | called by mutect2, pindel, varscan2
- KNTC1 | c.4779del p.H1594Tfs*2 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- LARP1 | c.3087del p.M1030Wfs*13 (on ENST00000518297 / NM_033551.3; = p.M953Wfs*13 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel, varscan2
- MCC | c.123_126del p.T42Rfs*22 | Frame Shift Del (DEL) | VAF 23/74 reads (31%) | called by mutect2, pindel, varscan2
- MROH1 | c.1669_1670insTGGGACGTG p.R556_G557insVGR | In Frame Ins (INS) | VAF 16/48 reads (33%) | called by mutect2, varscan2
- MYO9A | c.4264del p.Y1422Ifs*8 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | called by mutect2, varscan2
- NEIL3 | c.1185dup p.S396* | Frame Shift Ins (INS) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- NEK1 | c.570del p.C191Vfs*18 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- NEK7 | c.192del p.V65Cfs*6 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | called by mutect2, pindel, varscan2
- NSMCE4A | c.796_797del p.E266Sfs*17 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- OR2D3 | c.234del p.R80Efs*24 | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | called by mutect2, pindel, varscan2
- P2RX1 | c.974dup p.F326Vfs*2 | Frame Shift Ins (INS) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- PDS5B | c.2170del p.R724Vfs*32 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- PHF20 | c.2611del p.L871Sfs*17 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel, varscan2
- PIGW | c.1341del p.K447Nfs*3 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | called by mutect2, varscan2
- POMT1 | c.280+6del | Splice Region (DEL) | VAF 9/75 reads (12%) | called by mutect2, pindel, varscan2
- PPIG | c.36del p.F12Lfs*115 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel, varscan2
- PRSS16 | c.1204del p.S402Pfs*3 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- PTPN23 | c.920del p.G307Efs*27 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by pindel, varscan2
- PXDN | c.2592del p.N865Mfs*25 | Frame Shift Del (DEL) | VAF 15/35 reads (43%) | called by mutect2, pindel, varscan2
- QSER1 | c.1893del p.E632Kfs*8 (on ENST00000399302; = p.E761Kfs*8 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- SLC13A4 | c.735dup p.S246Qfs*16 | Frame Shift Ins (INS) | VAF 15/139 reads (11%) | called by mutect2, varscan2
- SLC25A25 | c.261del p.F87Lfs*46 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- SMARCC1 | c.998del p.P333Lfs*35 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- SNED1 | c.1474del p.L492Wfs*19 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel, varscan2
- SPATA13 | c.131A>G p.N44S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- SPTBN2 | c.2771del p.P924Qfs*35 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | called by mutect2, pindel, varscan2
- STAT3 | c.1226_1227del p.K409Tfs*18 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- SZT2 | c.6924del p.L2309Cfs*25 (on ENST00000634258 / NM_001365999.1; = p.L2252Cfs*25 on NM_015284.4) | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- TARS3 | c.1271del p.F424Sfs*67 | Frame Shift Del (DEL) | VAF 12/23 reads (52%) | called by mutect2, varscan2
- TSLP | c.216+1_216+5dup | Frame Shift Ins (INS) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- TTC7B | c.184dup p.L62Pfs*16 | Frame Shift Ins (INS) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- TTN | c.45713del p.N15238Mfs*7 (on ENST00000591111; = p.N7814Mfs*7 on NM_003319.4) | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel
- TTN | c.19373del p.N6458Mfs*74 (on ENST00000591111; = p.N5531Mfs*74 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- UBR3 | c.3504dup p.V1169Sfs*19 | Frame Shift Ins (INS) | VAF 6/16 reads (38%) | called by mutect2, pindel, varscan2
- VPS13A | c.5434dup p.M1812Nfs*5 | Frame Shift Ins (INS) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- YLPM1 | c.1778del p.P593Hfs*54 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.7668_7669del p.Q2557Efs*21 | Frame Shift Del (DEL) | VAF 19/60 reads (32%) | called by pindel, varscan2
- ZFHX3 | c.2287del p.E763Sfs*61 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel
- ZNF460 | c.915del p.K306Nfs*158 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- ZNF548 | c.1038dup p.R347* | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- ZNF704 | c.1151del p.K384Sfs*59 | Frame Shift Del (DEL) | VAF 21/107 reads (20%) | called by mutect2, pindel, varscan2
- ZSCAN2 | c.911del p.K304Sfs*74 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- ACSL4 | c.1776G>A p.L592= (on ENST00000340800 / NM_022977.2; = p.L551= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV100538850; called by muse, mutect2
- ACTA1 | c.24C>T p.T8= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs762659680, COSV100796781; called by muse, mutect2, varscan2
- ACTR1B | c.234C>T p.G78= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1279856749, COSV56704120; called by muse, mutect2, varscan2
- AGO4 | c.504C>T p.G168= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100943034; called by muse, mutect2, varscan2
- AGXT | c.1125C>T p.R375= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs528663088, CD013633, COSV100280223; called by muse, mutect2, varscan2
- AMBRA1 | c.3786C>T p.S1262= (on ENST00000458649 / NM_001367468.1; = p.S1172= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs1350999158, COSV54049359; called by muse, mutect2, varscan2
- ANXA4 | c.102C>T p.T34= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs151130421; called by mutect2, varscan2
- ARHGAP27 | c.2049G>A p.S683= (on ENST00000428638 / NM_001282290.1; = p.S342= on NM_199282.3) | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1300180091, COSV100976581; called by muse, mutect2, varscan2
- ASTN2 | c.3654G>A p.Q1218= (on ENST00000313400 / NM_001365069.1; = p.Q1167= on NM_014010.5) | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV99941213; called by muse, mutect2, varscan2
- ATAD2 | c.3621C>T p.D1207= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV54879844, COSV99785071; called by mutect2, varscan2
- BNIPL | c.624C>T p.H208= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as rs199934180, COSV54846485; called by muse, mutect2, varscan2
- C16orf89 | c.295C>T p.L99= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs371179598; called by muse, mutect2, varscan2
- CCN4 | c.381G>T p.G127= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1311361734, COSV99137287; called by mutect2, varscan2
- CD151 | c.498C>T p.D166= | Silent (SNP) | VAF 4/82 reads (5%) | catalogued as COSV100431854; called by muse, mutect2
- CD180 | c.1275C>T p.L425= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as rs1166806134, COSV99842325; called by muse, mutect2
- CD247 | c.18T>C p.L6= | Silent (SNP) | VAF 7/129 reads (5%) | called by muse, mutect2
- CDKN2B | c.306C>T p.A102= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99439616; called by muse, mutect2
- CKB | c.75C>A p.A25= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV100818939; called by muse, mutect2, varscan2
- CLSTN1 | c.1131C>T p.V377= (on ENST00000377298 / NM_001009566.3; = p.V367= on NM_014944.4) | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs769809592, COSV100790724; called by muse, mutect2, varscan2
- CNOT1 | c.6657G>A p.V2219= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV99800819; called by muse, mutect2, varscan2
- COL6A1 | c.2841G>A p.S947= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs768757964, COSV100720372; called by muse, mutect2, varscan2
- CRTAC1 | c.924C>T p.I308= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV54001902; called by muse, mutect2, varscan2
- CSNK1G2 | c.528G>A p.P176= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as rs755824841, COSV99730118; called by muse, mutect2, varscan2
- CSNK2A2 | c.888T>C p.P296= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV99345380; called by muse, mutect2, varscan2
- CTSD | c.807C>T p.Y269= | Silent (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- DNAAF5 | c.675G>T p.V225= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99860123; called by muse, mutect2
- DUSP10 | c.1116G>A p.R372= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV100100693; called by muse, mutect2
- DYNC1I1 | c.1815T>C p.Y605= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV61472805; called by muse, mutect2
- ENTPD7 | c.1152A>G p.A384= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100978467; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1080G>A p.A360= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as rs1240702515, COSV51618808; called by muse, mutect2
- FAXDC2 | c.660C>A p.A220= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV100303969; called by muse, mutect2, varscan2
- FREM2 | c.3504T>C p.S1168= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV99749936; called by muse, mutect2, varscan2
- FYB2 | c.1491C>A p.S497= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100599694, COSV58584794; called by muse, mutect2, varscan2
- GABRB3 | c.207C>T p.I69= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs770214111, COSV54662945; called by muse, mutect2, varscan2
- GCC2 | c.2304A>G p.S768= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100565572; called by muse, mutect2, varscan2
- GPC1 | c.861C>T p.D287= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs555091554, COSV50866379; called by muse, mutect2, varscan2
- GPR179 | c.1065G>A p.L355= (on ENST00000621958; = p.L354= on NM_001004334.4) | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs1362569502; called by muse, mutect2, varscan2
- GPSM1 | c.1641G>A p.Q547= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs782318613, COSV99396053; called by muse, mutect2
- GRM7 | c.2340A>G p.V780= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV63134707; called by muse, mutect2, varscan2
- GSPT2 | c.1725C>T p.F575= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV61213999; called by muse, mutect2, varscan2
- HDAC7 | c.1779G>A p.P593= (on ENST00000427332; = p.P632= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs753855692, COSV99316671; called by muse, varscan2
- HMCN1 | c.3891C>A p.T1297= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV99633130; called by muse, mutect2
- HOXA3 | c.180C>T p.G60= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV100415599; called by muse, mutect2
- ITGA10 | c.2376C>T p.D792= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV100994983; called by muse, mutect2, varscan2
- ITGB3 | c.555G>A p.K185= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV71385358; called by muse, mutect2, varscan2
- KCNA6 | c.984C>A p.G328= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs200079703, COSV54974703, COSV54977171, COSV99768734; called by muse, mutect2, varscan2
- KCND1 | c.1584G>A p.L528= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs1557057964, COSV99502080; called by muse, mutect2
- KCTD1 | c.168C>T p.I56= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs756597500, COSV100518039; called by muse, mutect2, varscan2
- L3MBTL1 | c.2223G>T p.S741= (on ENST00000418998 / NM_001377303.1; = p.S651= on NM_015478.7) | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100917029; called by mutect2, varscan2
- LAMA5 | c.693G>T p.V231= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99441336; called by muse, mutect2, varscan2
- LEPR | c.3303G>A p.S1101= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs755626079, COSV62745820; called by muse, mutect2, varscan2
- LRRC4 | c.1140C>A p.S380= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99975146; called by mutect2, varscan2
- LRRC45 | c.1383G>A p.A461= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs750284717, COSV100141912; called by muse, mutect2, varscan2
- LRRK2 | c.2724T>C p.S908= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100110861; called by muse, mutect2, varscan2
- LSM14A | c.1038C>T p.N346= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV101471737; called by muse, mutect2, varscan2
- MCM7 | c.1815C>A p.T605= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100385077; called by muse, mutect2, varscan2
- MCPH1 | c.813A>G p.A271= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100766013; called by muse, mutect2, varscan2
- MEOX2 | c.120G>A p.E40= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100012385; called by muse, mutect2, varscan2
- MFSD14B | c.597G>A p.V199= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV100942741; called by muse, mutect2, varscan2
- MRGPRX4 | c.663A>G p.T221= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as rs759820754, COSV100049778; called by muse, mutect2, varscan2
- MTCL1 | c.4413C>T p.D1471= (on ENST00000306329 / NM_001378206.1; = p.D1152= on NM_015210.4) | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs1171197508, COSV100095240; called by muse, mutect2
- MUC5B | c.10359C>T p.T3453= | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as COSV101500605; called by muse, mutect2
- MYO18B | c.5652G>A p.R1884= | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as COSV100124505; called by muse, mutect2
- MYO6 | c.9T>C p.D3= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100889391; called by muse, mutect2, varscan2
- MYO7B | c.2130C>T p.N710= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs756866229, COSV101268330; called by muse, mutect2, varscan2
- MYT1 | c.2355G>A p.K785= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100115151; called by muse, mutect2, varscan2
- NAE1 | c.978A>C p.R326= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99323236; called by muse, mutect2, varscan2
- NARF | c.627C>T p.F209= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs138767616; called by muse, mutect2, varscan2
- NDUFB7 | c.384C>T p.P128= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs1318968818, COSV53108983, COSV99295158; called by muse, mutect2, varscan2
- NECTIN2 | c.1098C>T p.I366= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs773570140, COSV99375154; called by mutect2, varscan2
- NOS1AP | c.787C>T p.L263= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV100723507; called by muse, mutect2
- NOTCH4 | c.1401C>T p.Y467= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV100900846; called by muse, mutect2
- NR0B1 | c.969C>A p.T323= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100973570; called by muse, mutect2
- OLAH | c.582A>G p.V194= (on ENST00000378228 / NM_001039702.3; = p.V247= on NM_018324.3) | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV100984821; called by muse, mutect2, varscan2
- OPN1MW | c.924C>T p.A308= | Silent (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- OR4C15 | c.888C>T p.H296= (on ENST00000314644; = p.H242= on NM_001001920.2) | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV100115930; called by muse, mutect2
- OTUD6A | c.108C>T p.T36= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs754168828, COSV57973222, COSV57973351; called by mutect2, varscan2
- PBX4 | c.312G>A p.A104= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs776372370, COSV52063837; called by muse, mutect2, varscan2
- PCDHA1 | c.1428G>A p.T476= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as rs377692615, COSV65373549; called by muse, mutect2, varscan2
- PLXNA3 | c.2163C>T p.C721= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs138065609, COSV63754984; called by muse, mutect2, varscan2
- PNPLA7 | c.1143C>A p.A381= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV99481153; called by muse, mutect2, varscan2
- POLA1 | c.474G>T p.L158= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100985694; called by muse, mutect2, varscan2
- PPCDC | c.39G>A p.L13= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV100738903; called by muse, mutect2, varscan2
- PPM1L | c.357G>A p.T119= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV101534463; called by mutect2, varscan2
- PPP3CC | c.774C>T p.Y258= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99252355; called by muse, mutect2, varscan2
- PRND | c.276C>T p.N92= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs370883023; called by muse, mutect2, varscan2
- PSMD5 | c.87G>A p.L29= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99270893; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1002C>T p.G334= (on ENST00000421990 / NM_001136042.2; = p.G316= on NM_025267.3) | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs765897068, COSV64182703; called by muse, mutect2, varscan2
- RARB | c.150G>A p.P50= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs374139996; called by muse, mutect2, varscan2
- RBBP4 | c.288A>G p.S96= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100995753; called by muse, mutect2, varscan2
- ROS1 | c.2133T>C p.D711= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100877509; called by muse, mutect2, varscan2
- SDK1 | c.2181C>T p.G727= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs368041669; called by muse, mutect2, varscan2
- SHROOM2 | c.3237C>T p.D1079= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs1041685317, COSV101098927; called by muse, mutect2, varscan2
- SLC25A43 | c.318G>A p.Q106= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV99474673; called by muse, mutect2, varscan2
- SLC35E4 | c.375C>T p.N125= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100299275; called by muse, mutect2, varscan2
- SLC38A9 | c.904C>T p.L302= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV59426138; called by muse, mutect2, varscan2
- SLC52A3 | c.834G>A p.T278= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs756359704, COSV54076608; ClinVar: likely benign; called by muse, mutect2, varscan2
- SORCS1 | c.3057C>T p.H1019= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99548691; called by muse, mutect2, varscan2
- TATDN2 | c.1104C>T p.V368= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99813663; called by muse, mutect2, varscan2
- TBCD | c.2571C>T p.D857= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as rs377189199; called by muse, mutect2
- TBX20 | c.576C>T p.T192= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs150384907; called by muse, mutect2, varscan2
- TEX15 | c.4017C>T p.A1339= (on ENST00000256246; = p.A1722= on NM_001350162.2) | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs766094508, COSV56356722; called by muse, mutect2, varscan2
- TGM4 | c.198G>A p.P66= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs777957841, COSV56094891; called by muse, mutect2, varscan2
- THOP1 | c.786G>A p.L262= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs766428675, COSV100310695; called by muse, mutect2, varscan2
- TMEM132A | c.370C>A p.R124= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs373031720, COSV99136475; called by muse, mutect2, varscan2
- TMEM132B | c.2991A>G p.L997= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as rs752253804, COSV100170465; called by muse, mutect2, varscan2
- TMEM132E | c.1008G>T p.R336= (on ENST00000321639; = p.R426= on NM_001304438.2) | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs764852466, COSV100396634; called by muse, mutect2, varscan2
- TMEM252 | c.129C>A p.A43= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV101051140; called by muse, mutect2, varscan2
- TMEM65 | c.366G>A p.A122= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs532224599, COSV52632339; called by muse, mutect2, varscan2
- TNFAIP3 | c.1986C>T p.C662= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs760291318, COSV52797793; called by muse, mutect2, varscan2
- TRRAP | c.3285A>G p.A1095= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs781927996, COSV100722728; called by muse, mutect2, varscan2
- TSC2 | c.3870C>T p.S1290= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs754466663, COSV54768110, COSV99554888; ClinVar: benign; called by muse, mutect2, varscan2
- TTC7B | c.651C>T p.F217= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV60631446; called by muse, mutect2, varscan2
- TTN | c.71625A>G p.L23875= (on ENST00000591111; = p.L16451= on NM_003319.4) | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs928953401, COSV100623047; called by muse, mutect2, varscan2
- TUBAL3 | c.1095G>A p.R365= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV66814143; called by muse, mutect2, varscan2
- TUBGCP2 | c.2265C>T p.C755= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs1299868855, COSV53306482; called by muse, mutect2, varscan2
- UBA1 | c.1758C>T p.R586= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs782655127, COSV100255953; called by muse, mutect2
- UBA7 | c.2517T>C p.R839= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100323706; called by muse, mutect2, varscan2
- UHRF1 | c.1152G>A p.A384= (on ENST00000612630 / NM_001290050.1; = p.A397= on NM_013282.4) | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs369756524; called by muse, mutect2, varscan2
- USP35 | c.87G>A p.A29= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV101489120; called by muse, mutect2, varscan2
- ZNF250 | c.1440G>A p.Q480= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99480985; called by muse, mutect2, varscan2
- ZNF510 | c.1641T>C p.N547= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV99793930; called by muse, mutect2, varscan2
- ZNF516 | c.2502G>T p.R834= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs1435127401, COSV101487337; called by muse, mutect2, varscan2
- ZNF646 | c.1944C>T p.A648= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV56219502; called by muse, mutect2
- ARPP19P1 | n.273C>T | RNA (SNP) | VAF 19/27 reads (70%) | called by muse, mutect2, varscan2
- CEP295 | c.5851-193del | Intron (DEL) | VAF 6/34 reads (18%) | catalogued as rs754124024; called by mutect2, pindel, varscan2
- CLCN5 | c.17-29032C>T | Intron (SNP) | VAF 16/49 reads (33%) | catalogued as COSV101067268; called by muse, mutect2, varscan2
- DNM1P46 | n.500_504del | RNA (DEL) | VAF 15/19 reads (79%) | called by mutect2, varscan2
- FGFR3 | c.*555C>T | 3'UTR (SNP) | VAF 5/32 reads (16%) | catalogued as rs755145822, COSV99602974; called by mutect2, varscan2
- MIR323A | n.64C>T | RNA (SNP) | VAF 36/87 reads (41%) | catalogued as rs754169604; called by muse, mutect2, varscan2
- MIR509-2 | n.57A>G | RNA (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- MTMR11 | c.*225del | 3'UTR (DEL) | VAF 16/105 reads (15%) | catalogued as rs782186576; called by mutect2, pindel, varscan2
- OBSCN | c.5138-255del | Intron (DEL) | VAF 12/95 reads (13%) | called by mutect2, pindel, varscan2
- PARGP1 | n.2152A>T | RNA (SNP) | VAF 25/315 reads (8%) | called by muse, mutect2
- PDPN | c.-110del | 5'UTR (DEL) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- SLC3A2 | chr11:62855025 del AAG | 5'Flank (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- WDR92 | c.-66G>A | 5'UTR (SNP) | VAF 14/38 reads (37%) | catalogued as COSV99718407; called by muse, mutect2, varscan2
- ZNF271P | n.1548T>C | RNA (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
